Somatic mutation profile of tumor specimen HCM-CSHL-0164-C20-06A (aliquot HCM-CSHL-0164-C20-06A-11D-A77E-36) from HCMI case HCM-CSHL-0164-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 51.5 years (18,816 days).
Specimen HCM-CSHL-0164-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b745cf1-dfe2-4753-9c9a-523428c124ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0164-C20-11A (Solid Tissue Normal), aliquot HCM-CSHL-0164-C20-11A-11D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a724dcab-7210-40ee-bfeb-29bc67ddc48c

The open-access MAF lists 137 somatic variants for this specimen: 101 protein-altering or splice-affecting, 26 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 26, Nonsense Mutation 8, Intron 3, RNA 3, 5'Flank 2, Frame Shift Del 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 58/227 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NR3C2 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 41/156 reads (26%) | catalogued as rs1131691921, CM127494, COSV60987868; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 157/481 reads (33%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs55726827; called by muse, mutect2, varscan2
- ADD2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781893870, COSV52469857; called by muse, mutect2, varscan2
- ANK2 | c.5726A>G p.K1909R | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as rs868828587; called by muse, mutect2, varscan2
- AR | c.1368_1406del p.G461_G473del | In Frame Del (DEL) | VAF 88/220 reads (40%) | catalogued as rs1314410183; called by mutect2, pindel, varscan2*
- CABP7 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs200796412; called by muse, mutect2, varscan2
- CARD11 | c.2818C>A p.L940I | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV62755943; called by muse, mutect2, varscan2
- CBX2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 136/560 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151114184; called by muse, mutect2, varscan2
- CCDC88C | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 99/391 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774584774, COSV66239736; called by muse, mutect2, varscan2
- CEMIP2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs777253304; called by muse, mutect2, varscan2
- CLEC4G | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1454674867; called by muse, mutect2, varscan2
- CNTN2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs758068126; called by muse, mutect2, varscan2
- CNTNAP4 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1328938055; called by muse, mutect2, varscan2
- COL11A1 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs745458984, COSV62191935; called by muse, mutect2, varscan2
- COX8C | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs755952756; called by muse, mutect2
- CPA3 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275808254, COSV56045944; called by muse, mutect2, varscan2
- DCC | c.2624C>T p.T875M | Missense Mutation (SNP) | VAF 135/316 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs747051148, COSV59139035; called by muse, mutect2, varscan2
- EBI3 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as rs762654891, COSV99696043; called by muse, mutect2, varscan2
- FANK1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV100904814; called by muse, mutect2, varscan2
- FAT4 | c.3562C>T p.Q1188* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as rs1336643545, COSV67897636; called by muse, mutect2, varscan2
- FPR3 | c.911T>G p.F304C | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59328946; called by muse, mutect2, varscan2
- GASK1B | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56706136; called by muse, mutect2
- GSDMC | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs759624672, COSV52696137; called by muse, mutect2
- GTPBP2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs771927723; called by muse, mutect2, varscan2
- HDAC5 | c.2793dup p.I932Hfs*24 | Frame Shift Ins (INS) | VAF 50/182 reads (27%) | catalogued as rs770174487; called by mutect2, varscan2
- HES6 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 135/576 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV54524916; called by muse, mutect2, varscan2
- IGHV5-51 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 134/550 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs782043169; called by muse, mutect2, varscan2
- KCNA3 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 128/348 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs749760182, COSV63901778; called by muse, mutect2, varscan2
- KCNT1 | c.3424G>A p.E1142K (on ENST00000488444; = p.D1168N on NM_020822.3) | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs747317425, COSV53707605, COSV53711347; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KDM5C | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 122/491 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs781782813; ClinVar: benign; called by muse, mutect2, varscan2
- NACAD | c.4168G>A p.V1390M | Missense Mutation (SNP) | VAF 85/400 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1035498664; called by muse, mutect2, varscan2
- NRP2 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 149/552 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs766899842; called by muse, mutect2, varscan2
- NUMA1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs190582413, COSV61191341; called by muse, mutect2, varscan2
- NYAP2 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs759695162; called by muse, mutect2, varscan2
- OR2AJ1 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1235580981; called by muse, mutect2
- PCDH12 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 169/381 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574087581, COSV51522153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGC3 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs753075137; called by muse, mutect2, varscan2
- PGR | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs150584881; called by muse, mutect2, varscan2
- PLEC | c.7511C>T p.T2504M (on ENST00000322810 / NM_201380.4; = p.T2394M on NM_000445.5) | Missense Mutation (SNP) | VAF 147/721 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as rs782618173, COSV59683824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTK2 | c.2941C>T p.R981* | Nonsense Mutation (SNP) | VAF 90/411 reads (22%) | catalogued as rs878926321; called by muse, mutect2, varscan2
- PTMS | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs867073491; called by muse, mutect2, varscan2
- RCVRN | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 34/98 reads (35%) | catalogued as rs142436628, COSV56841284; called by muse, mutect2, varscan2
- RYR3 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs377624442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIN3B | c.3469C>T p.R1157C | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs139041823; called by muse, mutect2, varscan2
- SNCAIP | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV54422659; called by muse, mutect2, varscan2
- SNX8 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs138849540; called by muse, mutect2, varscan2
- SOX11 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58983641; called by muse, mutect2, varscan2
- SPAG17 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs781719346, COSV60455732; called by muse, mutect2, varscan2
- SPATA31D1 | c.2782A>T p.I928F | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.159); catalogued as rs888563273; called by muse, mutect2, varscan2
- SYDE1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as rs752989406, COSV61442534; called by muse, mutect2, varscan2
- TAFA5 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1485482271; called by muse, mutect2, varscan2
- TERT | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs1060503009, COSV57211979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLE4 | c.467A>T p.Q156L | Missense Mutation (SNP) | VAF 71/427 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV54639041; called by muse, mutect2, varscan2
- ZBTB7B | c.137G>A p.R46H (on ENST00000292176; = p.R80H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as rs140676784; called by muse, mutect2, varscan2
- ZFHX3 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs370398587; called by muse, mutect2, varscan2
- ZMYM1 | c.2943A>T p.L981F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.637); catalogued as rs751374388; called by muse, mutect2, varscan2
- ZNF7 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); catalogued as rs146091107; called by muse, mutect2, varscan2
- ALDH1L2 | c.2662G>C p.D888H | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP2A2 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 109/426 reads (26%) | called by muse, mutect2, varscan2
- APC | c.4192_4193del p.R1399Ffs*9 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | called by pindel, varscan2
- BCORL1 | c.3895C>T p.R1299* | Nonsense Mutation (SNP) | VAF 95/190 reads (50%) | called by muse, mutect2, varscan2
- BRWD3 | c.1129T>G p.L377V | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- DCC | c.3498A>C p.E1166D | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.139); called by muse, mutect2
- DNHD1 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- EFCAB7 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- EFR3A | c.1543A>C p.I515L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXW9 | c.808G>T p.V270L (on ENST00000587955; = p.V280L on NM_032301.3) | Missense Mutation (SNP) | VAF 90/385 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- GDPD4 | c.974G>T p.R325I | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- GRAMD2A | c.756A>T p.R252S | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- GRM6 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 158/717 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- HK3 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 99/416 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFNA17 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- IQSEC2 | c.1191T>A p.Y397* (on ENST00000642864 / NM_001111125.3; = p.Y192* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 60/261 reads (23%) | called by muse, mutect2, varscan2
- KHDC1 | c.188C>G p.T63S | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- KIF13A | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- KIF4A | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LGR5 | c.2555T>A p.I852N | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- LRSAM1 | c.341A>C p.N114T | Missense Mutation (SNP) | VAF 131/508 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MS4A7 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NFKBIZ | c.1253T>C p.F418S | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2G2 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- OR52L1 | c.361T>G p.F121V | Missense Mutation (SNP) | VAF 105/323 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PASD1 | c.2084A>G p.E695G | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- POLR1D | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A9 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC34A2 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMARCA5 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SNAPC1 | c.571_577del p.K191* | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | called by mutect2, pindel
- TCF7L2 | c.1455G>T p.K485N (on ENST00000355995 / NM_001367943.1; = p.K462N on NM_030756.5) | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- TNKS2 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRMT44 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBN2 | c.2909T>G p.L970R | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- WNK4 | c.2747C>G p.P916R | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZFHX4 | c.3177G>C p.K1059N | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ZFP37 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF106 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.328); called by muse, mutect2
- ZNF292 | c.6075G>C p.L2025F | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZNF747 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 125/388 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ZNF831 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- ABCB11 | c.678G>A p.S226= | Silent (SNP) | VAF 78/293 reads (27%) | catalogued as rs777962265; called by muse, mutect2, varscan2
- ABCC12 | c.2604C>A p.T868= | Silent (SNP) | VAF 69/532 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.189G>T p.R63= | Silent (SNP) | VAF 30/368 reads (8%) | called by muse, mutect2
- ANK2 | c.2508T>A p.P836= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- B3GNT7 | c.597C>G p.L199= | Silent (SNP) | VAF 56/237 reads (24%) | called by muse, mutect2, varscan2
- BCOR | c.3642T>C p.L1214= (on ENST00000378444 / NM_001123385.2; = p.L1180= on NM_017745.6) | Silent (SNP) | VAF 100/437 reads (23%) | called by muse, mutect2, varscan2
- CHRNA7 | c.1293G>A p.P431= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs775002981, COSV100181613; called by mutect2, varscan2
- CLOCK | c.498T>A p.V166= | Silent (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- COL5A1 | c.4707G>T p.P1569= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs370009851, COSV65668232; called by muse, varscan2
- CRB2 | c.681C>T p.C227= | Silent (SNP) | VAF 85/329 reads (26%) | catalogued as COSV63504673; called by muse, mutect2, varscan2
- FADS3 | c.1167C>T p.F389= | Silent (SNP) | VAF 87/318 reads (27%) | called by muse, mutect2, varscan2
- GASK1B | c.579A>T p.P193= | Silent (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- HSPG2 | c.1683C>T p.P561= | Silent (SNP) | VAF 44/169 reads (26%) | catalogued as rs779806460; called by muse, mutect2, varscan2
- MMP3 | c.1155G>A p.V385= | Silent (SNP) | VAF 58/227 reads (26%) | called by muse, mutect2, varscan2
- MUC16 | c.6453T>A p.T2151= | Silent (SNP) | VAF 14/201 reads (7%) | called by muse, mutect2
- PAX3 | c.999G>A p.P333= | Silent (SNP) | VAF 111/401 reads (28%) | catalogued as rs913226154, COSV100399897; called by muse, varscan2
- PCLO | c.6528C>A p.V2176= | Silent (SNP) | VAF 57/169 reads (34%) | catalogued as COSV61629821; called by muse, mutect2, varscan2
- RTN1 | c.1101G>A p.S367= | Silent (SNP) | VAF 92/321 reads (29%) | catalogued as rs912145580, COSV50720712; called by muse, mutect2, varscan2
- SEC24B | c.2985A>G p.V995= | Silent (SNP) | VAF 40/134 reads (30%) | called by muse, mutect2, varscan2
- SYT9 | c.243G>A p.P81= | Silent (SNP) | VAF 36/390 reads (9%) | catalogued as rs752667061, COSV59618348; called by muse, mutect2
- TFPI | c.423T>C p.Y141= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs1432928818; called by muse, mutect2, varscan2
- TNFRSF18 | c.573G>A p.Q191= | Silent (SNP) | VAF 98/386 reads (25%) | catalogued as rs749873829; called by muse, mutect2, varscan2
- TRIM72 | c.1281C>T p.Y427= | Silent (SNP) | VAF 28/302 reads (9%) | catalogued as rs969863188; called by muse, mutect2
- UHRF1 | c.1608G>T p.V536= (on ENST00000612630 / NM_001290050.1; = p.V549= on NM_013282.4) | Silent (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- VPS13D | c.9162G>C p.V3054= | Silent (SNP) | VAF 45/194 reads (23%) | called by muse, mutect2, varscan2
- ZNF544 | c.1503C>T p.F501= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as rs1179656357; called by muse, mutect2, varscan2
- ATRX | c.4810-47_4810-46insG | Intron (INS) | VAF 27/117 reads (23%) | called by mutect2, pindel, varscan2
- CCDC51 | chr3:48440392 G>A | 5'Flank (SNP) | VAF 95/347 reads (27%) | called by muse, mutect2, varscan2
- COL16A1 | c.2772+14A>C | Intron (SNP) | VAF 32/452 reads (7%) | called by muse, mutect2
- CST9LP1 | n.183G>C | RNA (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- LINC01973 | n.1696G>A | RNA (SNP) | VAF 116/489 reads (24%) | catalogued as rs372748711; called by muse, mutect2, varscan2
- SHLD2P3 | n.2496C>T | RNA (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- SYT6 | c.*106C>T | 3'UTR (SNP) | VAF 39/201 reads (19%) | catalogued as rs1457051114; called by muse, mutect2, varscan2
- TBC1D4 | c.-43_-35del | 5'UTR (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- TMEM165 | c.433+60C>T | Intron (SNP) | VAF 59/232 reads (25%) | called by muse, mutect2, varscan2
- UBQLN1 | chr9:83712610 C>A | 5'Flank (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
